Somatic mutation profile of tumor specimen TCGA-EY-A210-01A (aliquot TCGA-EY-A210-01A-11D-A159-09) from TCGA case TCGA-EY-A210, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 82.4 years (30,095 days).
Specimen TCGA-EY-A210-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b196c542-93d1-40a1-8bb6-1daf4cc1180e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A210-10A (Blood Derived Normal), aliquot TCGA-EY-A210-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e328e0f-b895-49c0-ab81-56b436754baf

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 20, Silent 16, Splice Site 3, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.539+1G>A p.X180_splice | Splice Site (SNP) | VAF 25/36 reads (69%) | catalogued as rs1566187856, CS002151, COSV57299313; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100089601; called by muse, mutect2, varscan2
- ADAMTS13 | c.1492C>G p.R498G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100747233; called by muse, mutect2, varscan2
- ATM | c.2905C>T p.L969F | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV99592055; called by muse, mutect2, varscan2
- CACNA1A | c.965A>T p.D322V | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV100801010, COSV100803275; called by muse, mutect2, varscan2
- CD276 | c.1219A>T p.N407Y (on ENST00000318443 / NM_001024736.2; = p.N189Y on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100573474; called by muse, mutect2, varscan2
- CEMIP | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs750368243, COSV99586282; called by muse, mutect2, varscan2
- CILP2 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs762973440, COSV52277312; called by muse, mutect2, varscan2
- CSMD2 | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs750515208, COSV53888438; called by muse, mutect2, varscan2
- CYP24A1 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as rs886056789, COSV99398620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DARS2 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.006); catalogued as COSV99508914; called by muse, mutect2, varscan2
- DENND2A | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as rs764039930, COSV52054933, COSV99327036; called by muse, mutect2, varscan2
- EGLN2 | c.843+2T>C p.X281_splice | Splice Site (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100393852; called by muse, mutect2, varscan2
- INPPL1 | c.1950C>T p.F650= | Splice Region (SNP) | VAF 38/94 reads (40%) | catalogued as rs780987682, COSV99996674; called by muse, mutect2, varscan2
- M1AP | c.1469C>G p.T490S | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV99284219; called by muse, mutect2, varscan2
- OR8B8 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs192662256, COSV100045281; called by muse, mutect2, varscan2
- PLG | c.1862C>A p.A621D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV100369595; called by mutect2, varscan2
- RELN | c.9052C>T p.R3018* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV59004300; called by muse, mutect2, varscan2
- RO60 | c.1555A>G p.M519V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1476445097, COSV100814443; called by muse, mutect2, varscan2
- SLC38A10 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99917945; called by muse, mutect2, varscan2
- SLC4A8 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV60656411, COSV60658344; called by muse, mutect2, varscan2
- SPIC | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54692104; called by muse, mutect2, varscan2
- SYNE2 | c.1371G>T p.L457F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100648528; called by muse, mutect2, varscan2
- ZBTB7B | c.1154+1G>T p.X385_splice (on ENST00000292176; = p.X419_splice on NM_001252406.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99421578; called by muse, varscan2
- ZNF362 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1352987659, COSV100987066; called by muse, mutect2, varscan2
- CCL18 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FOXA2 | c.498_499dup p.L167Rfs*15 (on ENST00000377115 / NM_153675.3; = p.L173Rfs*15 on NM_021784.5) | Frame Shift Ins (INS) | VAF 76/188 reads (40%) | called by mutect2, pindel, varscan2
- RANBP2 | c.9216_9227del p.D3073_P3076del | In Frame Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- SCNM1 | c.270dup p.H91Tfs*4 | Frame Shift Ins (INS) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- BEST3 | c.393C>T p.Y131= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV56995325, COSV99876419; called by muse, mutect2, varscan2
- DOK6 | c.249C>A p.I83= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs974750131, COSV101235012; called by muse, mutect2, varscan2
- ELAVL2 | c.282G>A p.E94= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs201108944, COSV56357220, COSV99807293; called by muse, mutect2, varscan2
- FGFR4 | c.1641C>T p.Y547= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs781092287, COSV99448489; called by muse, varscan2
- IQUB | c.423C>A p.G141= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV100227381; called by muse, mutect2, varscan2
- KIR3DL1 | c.573G>T p.G191= | Silent (SNP) | VAF 133/179 reads (74%) | catalogued as COSV100428955; called by muse, mutect2, varscan2
- LIPA | c.1164T>C p.Y388= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV100290442; called by muse, mutect2, varscan2
- LRP5 | c.4485G>T p.P1495= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99592652; called by muse, varscan2
- MUC5B | c.17013C>T p.G5671= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101500812; called by muse, mutect2, varscan2
- MYO5B | c.540C>T p.F180= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as rs370497980; called by muse, mutect2, varscan2
- NTF3 | c.216G>A p.P72= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1391494696, COSV58417558; called by muse, mutect2
- SARM1 | c.1464G>A p.A488= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99135049; called by muse, mutect2, varscan2
- SDHAF3 | c.301T>C p.L101= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV100836535; called by muse, mutect2, varscan2
- SLC26A7 | c.1056A>C p.I352= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99404446; called by muse, mutect2, varscan2
- THSD4 | c.2292G>C p.V764= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV99967224; called by muse, mutect2, varscan2
- ZNF518B | c.321G>A p.A107= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs1287568633, COSV100456514; called by muse, mutect2, varscan2
